Gene-level copy-number profile of tumor specimen TCGA-DD-AADD-01A from TCGA case TCGA-DD-AADD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 51.3 years (18,752 days).
Specimen TCGA-DD-AADD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.0c10287a-2cf1-451e-9827-da622c068c5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/856671c4-1411-42d4-918e-297a2fafec7d

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,286; copy number 3: 6,308; copy number 4: 11,652; copy number 5: 24,679; copy number 6: 7,711; copy number 7: 1,031; copy number 8: 988; copy number 9: 3,048; copy number 10: 1,409; copy number 11: 617; copy number 12: 34; copy number 14: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADD-01A-11D-A40Q-01): tumor purity 0.84, ploidy 4.03, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 703 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:185,734,391–187,714,735, 22 genes, copy number 11 (within-gene range 10–11): HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1.
- chr1:189,775,465–196,065,235, 54 genes, copy number 11 (within-gene range 10–11): LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL138778.1, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, AL353072.2, AL353709.1, LINC01724.
- chr7:70,972–8,752,961, 204 genes, copy number 11 (within-gene range 9–11) (broad region; genes not listed).
- chr8:43,493,937–53,162,987, 107 genes, copy number 11–12 (broad region; genes not listed).
- chr8:56,160,909–60,623,644, 63 genes, copy number 11 (within-gene range 10–11) (broad region; genes not listed).
- chr8:67,422,038–71,228,629, 53 genes, copy number 12–14 (within-gene range 8–14): CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1.
- chr8:81,244,156–93,029,839, 159 genes, copy number 11 (broad region; genes not listed).
- chr8:106,215,763–107,648,032, 15 genes, copy number 11: SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13.
- chr8:110,555,408–112,148,825, 14 genes, copy number 11: AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P.
- chr20:22,054,074–22,746,991, 12 genes, copy number 11: LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
